Surgical pathology report (de-identified scan), TCGA case TCGA-60-2709, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2709-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R LYMPH NODE
B. 4L LYMPH NODE
C. LEVEL 7 LYMPH NODE
D. 4R LYMPH NODE
E. 4L LYMPH NODE
F. LEVEL 7 LYMPH NOIDE
G. LEVEL 5 LYMPH NODE
H. LEVEL 6 LYMPH NODE
I. LEVEL 6 LYMPH NODE
J. LEVEL 10 LYMPH NODE
K. LEFT UPPER LOBE WITH SUPERIOR SEGMENT OF LOWER LOBE
L. LEVEL ELEVEN LYMPH NODE

CLINICAL HISTORY: Left lung ca.

PRE-OPERATIVE DIAGNOSIS: None

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA, FSB, FSC: No tumor seen, reported to OR4 at 12:02pm by [REDACTED]

FSG, FSH: No tumor seen, reported to OR4 at 1:48pm by [REDACTED]

FSK: Bronchial margin, negative for malignancy by [REDACTED] at [REDACTED]

GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL

The specimen is received fresh in a single container labeled [REDACTED] and designated "4R right distal paratracheal" and consists of a single portion of tan lymph node measuring 0.4x0.3x0.2cm. The entire specimen is submitted in block FSA for frozen section diagnosis.

B. 4L LEFT DISTAL PARATRACHEAL

The specimen is received fresh in a single container labeled [REDACTED] and designated "4L left distal paratracheal" and consists of a single tan lymph node measuring 0.6x0.4x0.2cm. The entire specimen is submitted in block FSB for frozen section diagnosis

[page 2 of 4]
[REDACTED]

C. LEVEL 7 LYMPH NODE

The specimen is received fresh in a single container labeled [REDACTED] and designated "level 7" and consists of a single portion of tan lymph node measuring 0.5x0.3x0.2cm. The entire specimen is submitted in block FSC for frozen section diagnosis. [REDACTED]

D. 4R LYMPH NODE

Received fresh is a single lymph node measuring 0.3x0.3x0.2cm. Entirely submitted in one cassette.

E. 4L LYMPH NODE

Received fresh are two fragments of pink tan lymphoid tissue measuring 0.4x0.2x0.2cm. Entirely submitted in one cassette.

F. LEVEL 7 LYMPH NODE

Received fresh is a single lymph node measuring 0.3x0.2x0.1cm. Entirely submitted in one cassette. [REDACTED]

G. LEVEL 5 LYMPH NODE

The specimen is received fresh in a single container labeled [REDACTED] designated "level 5 lymph node" and consists of a single tan lymph node measuring 1.1x0.7x0.5cm. The entire specimen is submitted in block FSG for frozen section diagnosis.

H. LEVEL 6 LYMPH NODE

The specimen is received fresh in a single container labeled [REDACTED] designated "level 6 lymph node" and consists of a single tan lymph node measuring 0.8x0.7x0.4cm. The entire specimen is submitted in block FSH for frozen section diagnosis. [REDACTED]

I. LEVEL 6 LYMPH NODE

Received fresh is a single lymph node measuring 1.1x0.4x0.3cm. Entirely submitted in one cassette.

J. LEVEL X LYMPH NODE

Received fresh is a single lymph node measuring 1.3x0.6x0.4cm. Entirely submitted in one cassette. [REDACTED]

K. LEFT UPPER LOBE WITH SUPERIOR SEGMENT OF LOWER LOBE

The specimen is received fresh in a container labeled with the patient name and designated "left upper lobe with superior segment of lower lobe". It consists of one lobe of the lung weighing 310gm. and measuring 15x13x4.2cm. Serial sectioning of the specimen reveals a white and grey tan tumor measuring 4.0x3.5x3.0cm. This tumor is 1cm. from the hilar bronchial resection margin and less than 0.1cm. from the pleural surface. Gross examination of the surface reveals a 1.5x0.6cm. induration area. One portion of tissue is submitted for frozen section examination. Representative sections are submitted in ten cassettes.

K1: frozen section

K2: bronchial margin

K3-K5: tumor with bronchus

K6-K8: tumor with inked pleural surface

K9-K10: random sections of lung

L. LEVEL ELEVEN LYMPH NODE

Received fresh are two fragments of pink tan tissue measuring 1.6x0.6x0.4cm. Entirely submitted in one cassette. [REDACTED]

[page 3 of 4]
DIAGNOSIS:

- A. 4R LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- B. 4L LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- C. LEVEL 7 LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- D. 4R LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- E. 4L LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- F. LEVEL 7 LYMPH NODE, BIOPSY:
-LYMPH NODE WITH AUTOLYTIC CHANGES, NO MALIGNANCY SEEN (0/1)
- G. LEVEL 5 LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- H. LEVEL 6 LYMPH NODE, BIOPSY:
-TWO LYMPH NODES, NEGATIVE FOR METASTASIS (0/2)
- I. LEVEL 6 LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- J. LEVEL 10 LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)
- K. LEFT UPPER LOBE WITH SUPERIOR SEGMENT OF LOWER LOBE, RESECTION:
-INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
-TUMOR SIZE 4X3.5X3CM.
-BRONCHIAL MARGIN OF RESECTION, NEGATIVE FOR TUMOR
-SEE TEMPLATE
- L. LEVEL 11 LYMPH NODE, BIOPSY:
-ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

Lung template (non-small cell lung cancer)

Surgical procedure:	lobectomy
Tumor location:	Peripheral LUL
Tumor size (greatest diameter):	4.0x3.5x3.0cm.
Tumor type:	squamous cell carcinoma
Histologic grade:	poorly differentiated
Angiolymphatic invasion:	absent
Bronchial margin (including distance from tumor):	negative
Visceral pleural involvement (T2):	absent
Satellite tumor(s) (T4):	no
Lymph node involvement: N1: Hilar(Level 10)	negative (0/1)
Peribronchial (Level 11-14)	negative (0/1)
N2: Mediastinal (Level 1-9)	negative (0/10)
N3: Contralateral side	NA
AJCC stage:	pT2N0Mx

[page 4 of 4]
Non-neoplastic lung; minimal change

Source: NCI Genomic Data Commons file 1981647a-a1d9-4619-a307-b4ffd1a3fcbf (TCGA-60-2709.F1E99E51-52E3-4F5D-B483-3C1B1EADD977.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).